Somatic mutation profile of tumor specimen CDDP-ACR8-TTP1-A (aliquot CDDP-ACR8-TTP1-A-1-0-D-A572-36) from CDDP_EAGLE case CDDP-ACR8, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 59 years.
Specimen CDDP-ACR8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cca0a56d-c818-4a42-b4ec-466d02b86931.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACR8-NB1-A (Blood Derived Normal), aliquot CDDP-ACR8-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2be41d1f-bd61-4ffe-b710-e79cf1d304d3

The open-access MAF lists 520 somatic variants for this specimen: 352 protein-altering or splice-affecting, 96 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 295, Silent 96, Intron 29, Nonsense Mutation 20, Frame Shift Del 19, RNA 17, 5'UTR 11, 5'Flank 7, Splice Site 6, 3'UTR 6, Splice Region 5, Frame Shift Ins 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 94/381 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV51023351; called by muse, mutect2, varscan2
- ABCA13 | c.4912G>T p.V1638L | Missense Mutation (SNP) | VAF 174/619 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV70030031; called by muse, mutect2, varscan2
- AC005833.1 | c.1510G>T p.A504S | Missense Mutation (SNP) | VAF 106/262 reads (40%) | SIFT deleterious, low confidence (0); catalogued as COSV52901234; called by muse, mutect2, varscan2
- ADAMTS18 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 104/370 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.051); catalogued as rs767266061; called by muse, mutect2, varscan2
- AFM | c.689T>A p.F230Y | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs1316273811; called by muse, mutect2, varscan2
- AGO3 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV55798272; called by muse, mutect2, varscan2
- AMER3 | c.1329C>G p.C443W | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58465928; called by muse, mutect2, varscan2
- ANGPT4 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs865925309; called by muse, mutect2, varscan2
- ANKRD30B | c.2881G>T p.E961* | Nonsense Mutation (SNP) | VAF 48/186 reads (26%) | catalogued as COSV57704511; called by muse, mutect2, varscan2
- ARHGAP28 | c.1189A>G p.K397E (on ENST00000383472 / NM_001366230.1; = p.K238E on NM_001010000.3) | Missense Mutation (SNP) | VAF 78/322 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1316838173; called by muse, mutect2, varscan2
- ASCC3 | c.4175G>T p.W1392L | Missense Mutation (SNP) | VAF 128/450 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768947987; called by muse, mutect2, varscan2
- ASPHD2 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs142083990; called by muse, mutect2, varscan2
- ASTN2 | c.1079G>C p.R360P | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.969); catalogued as COSV57761242; called by muse, varscan2
- ATP8B1 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 135/428 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.193); catalogued as COSV52175901; called by muse, mutect2, varscan2
- BANF2 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773946149; called by muse, mutect2, varscan2
- BCL7B | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs146655849; called by muse, mutect2, varscan2
- CALCOCO1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs537375925; called by muse, mutect2, varscan2
- CALHM4 | c.458G>T p.R153L (on ENST00000368596 / NM_001366078.1; = p.R10L on NM_001256887.3) | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV63985963; called by muse, mutect2, varscan2
- CAVIN2 | c.783G>C p.K261N | Missense Mutation (SNP) | VAF 137/488 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58423804; called by muse, mutect2, varscan2
- CCDC148 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 124/527 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.653); catalogued as rs377450369; called by muse, mutect2, varscan2
- CDC14C | c.1193C>T p.T398I (on ENST00000428251; = p.T291I on NM_152627.3) | Missense Mutation (SNP) | VAF 66/338 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752282345; called by muse, varscan2
- CDIN1 | c.451G>T p.G151* (on ENST00000437989; = p.G53* on NM_032499.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 56/274 reads (20%) | catalogued as COSV100589912; called by muse, mutect2, varscan2
- CDKN2A | c.57del p.A20Rfs*6 | Frame Shift Del (DEL) | VAF 80/204 reads (39%) | catalogued as CD0910255; called by mutect2, pindel, varscan2
- CHKB | c.523C>A p.H175N | Missense Mutation (SNP) | VAF 170/531 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56418126; called by muse, mutect2, varscan2
- CNTNAP2 | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 127/742 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV62158012; called by muse, mutect2, varscan2
- COL6A5 | c.4831C>A p.P1611T | Missense Mutation (SNP) | VAF 126/541 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV55203148; called by muse, mutect2, varscan2
- CRB1 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 99/365 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as COSV66328763; called by muse, mutect2, varscan2
- DOCK1 | c.4519A>G p.M1507V | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs1259544454; called by muse, mutect2, varscan2
- DUSP8 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770644131; called by muse, mutect2, varscan2
- EHMT1 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100603489; called by muse, mutect2, varscan2
- ELAVL2 | c.101C>G p.T34R | Missense Mutation (SNP) | VAF 129/326 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as COSV56365650; called by muse, mutect2, varscan2
- EYS | c.4402G>T p.D1468Y | Missense Mutation (SNP) | VAF 162/476 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.564); catalogued as CM1410765; called by muse, mutect2, varscan2
- FAM47C | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 98/156 reads (63%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.939); catalogued as COSV63723864; called by muse, mutect2, varscan2
- FAT3 | c.11831C>G p.P3944R | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53140202; called by muse, mutect2, varscan2
- FCRL1 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.659); catalogued as COSV100839801, COSV63826569; called by muse, mutect2, varscan2
- FMN2 | c.3277G>A p.G1093R | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs778552457, COSV60438623; called by muse, varscan2
- FMO3 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 106/335 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs951676823, CM994677; called by muse, mutect2, varscan2
- GFRAL | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV61235680; called by muse, mutect2, varscan2
- GIMAP6 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 133/566 reads (23%) | catalogued as COSV61033791; called by muse, mutect2, varscan2
- GJA10 | c.175C>G p.P59A | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350646629; called by muse, mutect2, varscan2
- GPR158 | c.2872C>A p.P958T | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV66268011, COSV66283827; called by muse, mutect2, varscan2
- GRIA1 | c.755del p.G252Vfs*5 | Frame Shift Del (DEL) | VAF 51/277 reads (18%) | catalogued as COSV53597752; called by mutect2, pindel, varscan2
- HSPA1L | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1314611285, COSV100989458; called by muse, mutect2, varscan2
- IGF2R | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs760458051; called by muse, mutect2, varscan2
- IGSF9B | c.3641G>A p.G1214D | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as rs748596293; called by muse, varscan2
- IL1RAP | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs779485745, COSV99299186; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.724G>T p.V242L (on ENST00000485419 / NM_001197113.1; = p.V166L on NM_014575.3) | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1361188535, COSV61843749; called by muse, mutect2, varscan2
- ITGA2B | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 51/201 reads (25%) | catalogued as rs74602141, CM099777; called by muse, mutect2, varscan2
- KIF1C | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 99/210 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275146785; called by muse, mutect2, varscan2
- KLHL42 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 129/546 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.074); catalogued as COSV67146099; called by muse, mutect2, varscan2
- LCTL | c.310C>A p.H104N | Missense Mutation (SNP) | VAF 91/355 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs866215011; called by muse, mutect2, varscan2
- LIMCH1 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 142/574 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1232125091; called by muse, mutect2, varscan2
- LRRK2 | c.2436A>T p.K812N | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as rs772759167; called by muse, mutect2, varscan2
- LYZL6 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 23/364 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.969); catalogued as rs985139063; called by muse, mutect2
- MAGEA12 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV100757094, COSV63295369; called by muse, mutect2, varscan2
- MFAP5 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 134/405 reads (33%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.652); catalogued as COSV100848118; called by muse, mutect2, varscan2
- MTMR14 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs765089025; called by muse, mutect2, varscan2
- N4BP2 | c.2751A>C p.K917N | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV54700243; called by muse, mutect2, varscan2
- NCCRP1 | c.718G>C p.G240R | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59212214; called by muse, mutect2, varscan2
- NOL6 | c.2209G>T p.V737L | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs200406834; called by muse, mutect2, varscan2
- NTRK3 | c.2418C>A p.C806* (on ENST00000360948 / NM_001012338.2; = p.C792* on NM_002530.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 81/260 reads (31%) | catalogued as COSV62313056; called by muse, mutect2, varscan2
- OR11L1 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63315747; called by muse, mutect2, varscan2
- OR2AK2 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1190537026; called by muse, mutect2, varscan2
- OR2T3 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 71/331 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV62083308; called by muse, mutect2, varscan2
- OR52E8 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs759536285, COSV101190186, COSV66205200; called by muse, mutect2, varscan2
- OR5AP2 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.893); catalogued as COSV57259377; called by muse, mutect2, varscan2
- OR5L2 | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.279); catalogued as rs1271195131, COSV65723501, COSV65725092; called by muse, mutect2, varscan2
- PAQR9 | c.902C>A p.P301Q | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61419214; called by muse, mutect2, varscan2
- PCDHA13 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV56552969; called by muse, mutect2, varscan2
- PCDHB12 | c.847C>A p.H283N | Missense Mutation (SNP) | VAF 91/369 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV53397748; called by muse, mutect2, varscan2
- PGK2 | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 77/314 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.858); catalogued as COSV59165480; called by muse, mutect2, varscan2
- PIWIL4 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as rs754765445, COSV54407034; called by muse, mutect2, varscan2
- PLEC | c.7108G>A p.V2370M (on ENST00000322810 / NM_201380.4; = p.V2260M on NM_000445.5) | Missense Mutation (SNP) | VAF 179/649 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); catalogued as COSV59619282; called by muse, mutect2, varscan2
- POLN | c.1174A>G p.I392V | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1422854806; called by muse, varscan2
- PRB3 | c.797C>T p.P266L (on ENST00000381842; = p.P308L on NM_006249.5) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.159); catalogued as rs1246078120; called by muse, mutect2, varscan2
- PRKCB | c.181G>T p.G61W | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100335580; called by muse, mutect2, varscan2
- PTAFR | c.905del p.K302Sfs*48 | Frame Shift Del (DEL) | VAF 80/339 reads (24%) | catalogued as COSV100544492; called by mutect2, pindel, varscan2
- PTPRC | c.335A>T p.H112L | Missense Mutation (SNP) | VAF 139/506 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV100722478; called by muse, mutect2, varscan2
- PTPRQ | c.6926C>T p.A2309V (on ENST00000616559; = p.A2276V on NM_001145026.2) | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs1255362660; called by muse, mutect2, varscan2
- ROBO4 | c.1514G>A p.R505K | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV60628313; called by muse, mutect2, varscan2
- RSPH6A | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as rs771185702, COSV55570390, COSV55572403; called by muse, varscan2
- SCN1A | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 110/384 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD1311676; called by muse, mutect2, varscan2
- SHISA2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs772223080; called by muse, mutect2, varscan2
- SLC12A8 | c.1771C>G p.H591D | Missense Mutation (SNP) | VAF 141/357 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV58870042; called by muse, mutect2, varscan2
- SLC17A9 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs371630761; called by muse, mutect2, varscan2
- SMARCA4 | c.939del p.A314Rfs*12 | Frame Shift Del (DEL) | VAF 47/162 reads (29%) | catalogued as COSV60810972, COSV60812379; called by pindel, varscan2
- SORCS3 | c.1114A>G p.R372G | Missense Mutation (SNP) | VAF 121/340 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs1403059749; called by muse, mutect2, varscan2
- SRCAP | c.4999C>T p.P1667S | Missense Mutation (SNP) | VAF 109/352 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV52667314; called by muse, mutect2, varscan2
- STXBP5L | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 89/466 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760939427; called by muse, mutect2, varscan2
- SYNE1 | c.7714G>A p.E2572K (on ENST00000367255 / NM_182961.4; = p.E2579K on NM_033071.3) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs886061209; ClinVar: uncertain significance; called by muse, varscan2
- TAS2R1 | c.622A>G p.M208V | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as rs749930009; called by muse, mutect2, varscan2
- TAS2R60 | c.326G>A p.W109* | Nonsense Mutation (SNP) | VAF 138/608 reads (23%) | catalogued as rs549397444; called by muse, mutect2, varscan2
- TECPR1 | c.1403G>C p.R468T | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV101130431, COSV65784871, COSV65785600; called by muse, mutect2, varscan2
- TLX1 | c.821T>A p.I274N | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs766001320, COSV64622473; called by muse, mutect2, varscan2
- TM6SF1 | c.685G>C p.G229R | Missense Mutation (SNP) | VAF 114/439 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.283); catalogued as COSV51944755; called by muse, mutect2, varscan2
- TMCO4 | c.1631G>T p.R544L | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53869617; called by muse, mutect2, varscan2
- TMEM37 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs757906562, COSV50026719; called by muse, mutect2, varscan2
- TNK2 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 104/248 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1466375877; called by muse, mutect2, varscan2
- TP53 | c.602del p.L201Cfs*46 | Frame Shift Del (DEL) | VAF 165/490 reads (34%) | catalogued as COSV52837759, COSV53037685; called by mutect2, pindel, varscan2
- TPO | c.348G>A p.T116= | Splice Region (SNP) | VAF 102/368 reads (28%) | catalogued as rs374499898; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBGCP5 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs371086875; called by muse, mutect2, varscan2
- UBAC1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs528238931, COSV65613970; called by mutect2, varscan2
- UFL1 | c.2192A>G p.Y731C | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs1257042316; called by muse, mutect2, varscan2
- UGT2B4 | c.56G>C p.S19T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100522615; called by muse, varscan2
- VWDE | c.4028C>A p.P1343H | Missense Mutation (SNP) | VAF 105/358 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51734054; called by muse, mutect2, varscan2
- XPNPEP1 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 96/351 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV59171333; called by muse, mutect2, varscan2
- XRCC2 | c.362G>C p.S121T | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV63769925; called by muse, mutect2, varscan2
- ZKSCAN1 | c.673-1G>A p.X225_splice | Splice Site (SNP) | VAF 13/92 reads (14%) | catalogued as rs764112440; called by muse, mutect2, varscan2
- ZNF2 | c.977A>T p.Y326F (on ENST00000611147 / NM_001291605.2; = p.Y313F on NM_021088.4) | Missense Mutation (SNP) | VAF 134/432 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.102); catalogued as rs773941682; called by muse, mutect2, varscan2
- ZNF423 | c.272C>T p.T91M (on ENST00000563137 / NM_001379286.1; = p.T83M on NM_015069.4) | Missense Mutation (SNP) | VAF 106/374 reads (28%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.576); catalogued as rs200710667, COSV52181840; called by muse, mutect2, varscan2
- A1CF | c.1498C>G p.P500A (on ENST00000373993 / NM_138932.2; = p.P492A on NM_014576.4) | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, varscan2
- ABCA6 | c.1592C>A p.S531Y | Missense Mutation (SNP) | VAF 74/308 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- ABCC11 | c.3583A>T p.M1195L | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACACB | c.6265C>G p.L2089V | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACAT1 | c.436-5C>A | Splice Region (SNP) | VAF 122/469 reads (26%) | called by muse, mutect2, varscan2
- ADAM22 | c.1932_1934del p.E644del | In Frame Del (DEL) | VAF 92/480 reads (19%) | called by pindel, varscan2
- ADAMTS12 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 89/406 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- ADAMTS7 | c.2333A>T p.N778I | Missense Mutation (SNP) | VAF 103/314 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ADAMTSL5 | c.243C>G p.C81W | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB2 | c.542del p.R181Pfs*97 | Frame Shift Del (DEL) | VAF 79/407 reads (19%) | called by mutect2, pindel, varscan2
- ADGRD2 | c.1547C>A p.T516K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.95); PolyPhen benign (0.029); called by muse, varscan2
- AGBL3 | c.1870A>G p.I624V | Missense Mutation (SNP) | VAF 72/422 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- AGXT2 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 193/851 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AL121758.1 | c.270G>C p.R90S | Missense Mutation (SNP) | VAF 91/343 reads (27%) | PolyPhen benign (0.412); called by muse, mutect2, varscan2
- ANGEL1 | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ANK3 | c.759G>T p.L253F | Missense Mutation (SNP) | VAF 94/446 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD30B | c.4070dup p.H1357Qfs*10 | Frame Shift Ins (INS) | VAF 23/116 reads (20%) | called by mutect2, pindel, varscan2
- ANKRD31 | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ANKRD33B | c.1042del p.A348Rfs*228 | Frame Shift Del (DEL) | VAF 18/96 reads (19%) | called by mutect2, varscan2
- APOBEC1 | c.575G>T p.C192F | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- APOBEC3A | c.585+2T>A p.X195_splice | Splice Site (SNP) | VAF 48/211 reads (23%) | called by muse, mutect2, varscan2
- ARHGAP5 | c.3969G>T p.M1323I (on ENST00000345122 / NM_001030055.2; = p.M1322I on NM_001173.3) | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ASTN2 | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.013); called by muse, varscan2
- BCL11A | c.1048A>G p.K350E (on ENST00000335712 / NM_001365609.1; = p.K384E on NM_018014.4) | Missense Mutation (SNP) | VAF 112/379 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BCL2L12 | c.704del p.R235Pfs*48 | Frame Shift Del (DEL) | VAF 118/625 reads (19%) | called by mutect2, pindel, varscan2
- BRCA2 | c.3004A>T p.N1002Y | Missense Mutation (SNP) | VAF 84/360 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRINP3 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 75/295 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- C10orf71 | c.3119G>T p.R1040I | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- C18orf32 | c.219A>C p.K73N | Missense Mutation (SNP) | VAF 91/382 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2orf16 | c.2823C>A p.S941R | Missense Mutation (SNP) | VAF 116/480 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CAPN14 | c.312G>C p.L104F | Missense Mutation (SNP) | VAF 67/224 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.6776C>A p.A2259D | Missense Mutation (SNP) | VAF 84/291 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC182 | c.319C>A p.R107S | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CD1D | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CD1E | c.156C>A p.H52Q | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD86 | c.606C>A p.S202R (on ENST00000330540 / NM_175862.5; = p.S196R on NM_006889.4) | Missense Mutation (SNP) | VAF 56/316 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- CDK11A | c.1162G>T p.A388S (on ENST00000378633 / NM_001313896.2; = p.A385S on NM_024011.4) | Missense Mutation (SNP) | VAF 87/259 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDK5R2 | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 186/612 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CEP112 | c.1292G>T p.R431M | Missense Mutation (SNP) | VAF 96/480 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CEP85L | c.1630G>T p.A544S | Missense Mutation (SNP) | VAF 55/339 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP54 | c.3401T>C p.L1134S | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- CFP | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- CNGB1 | c.2111T>C p.L704P | Missense Mutation (SNP) | VAF 163/613 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CNOT4 | c.1762C>G p.P588A (on ENST00000541284 / NM_001190850.1; = p.P585A on NM_001190849.2) | Missense Mutation (SNP) | VAF 60/274 reads (22%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COBLL1 | c.3379A>T p.N1127Y (on ENST00000392717; = p.N1089Y on NM_014900.5) | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- COBLL1 | c.3238A>T p.T1080S (on ENST00000392717; = p.T1042S on NM_014900.5) | Missense Mutation (SNP) | VAF 151/500 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- COL11A1 | c.411del p.L138Cfs*30 | Frame Shift Del (DEL) | VAF 182/672 reads (27%) | called by mutect2, pindel, varscan2
- COL27A1 | c.2458G>T p.G820C | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- COL6A6 | c.1556T>C p.L519P | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COLEC12 | c.459G>T p.L153F | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CPNE9 | c.351G>C p.Q117H | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CREBBP | c.4936C>G p.L1646V | Missense Mutation (SNP) | VAF 122/397 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CRIM1 | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- CWH43 | c.1753G>C p.A585P | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- DCHS1 | c.4969C>A p.L1657I | Missense Mutation (SNP) | VAF 118/455 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX6 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 96/280 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLC1 | c.1660G>A p.D554N (on ENST00000276297 / NM_001348081.2; = p.D117N on NM_006094.5) | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DLL1 | c.1949_1960del p.D650_A653del | In Frame Del (DEL) | VAF 19/104 reads (18%) | called by mutect2, pindel, varscan2
- DLL3 | c.1444G>C p.G482R | Missense Mutation (SNP) | VAF 95/310 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DNAH5 | c.10493G>T p.G3498V | Missense Mutation (SNP) | VAF 260/733 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DNAH9 | c.6811C>A p.L2271M | Missense Mutation (SNP) | VAF 89/251 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSG2 | c.1720G>T p.D574Y | Missense Mutation (SNP) | VAF 159/552 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EGR4 | c.1663G>A p.E555K (on ENST00000545030; = p.E452K on NM_001965.4) | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ELMO1 | c.1803C>A p.H601Q | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ENAM | c.54+1G>T p.X18_splice | Splice Site (SNP) | VAF 130/338 reads (38%) | called by muse, mutect2, varscan2
- ERICH4 | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by muse, mutect2
- EWSR1 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 82/332 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- FAM133A | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FAM135B | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 37/203 reads (18%) | called by muse, mutect2, varscan2
- FLRT1 | c.1625_1660del p.E542_L553del | In Frame Del (DEL) | VAF 40/82 reads (49%) | called by mutect2, pindel
- FOXD3 | c.199C>A p.H67N | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM2 | c.3762G>T p.L1254F | Missense Mutation (SNP) | VAF 88/338 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- FSHB | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 105/414 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- FSHR | c.1456G>T p.A486S | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRA1 | c.835G>T p.V279L | Missense Mutation (SNP) | VAF 164/555 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- GABRB2 | c.1191+5G>C | Splice Region (SNP) | VAF 39/134 reads (29%) | called by muse, mutect2, varscan2
- GALNTL5 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 317/716 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GOLGA6B | c.1988A>T p.E663V | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GPD1 | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 70/314 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR35 | c.835A>G p.M279V | Missense Mutation (SNP) | VAF 77/294 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRIN2 | c.839G>C p.C280S | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRID2IP | c.1755C>A p.S585R | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- HCN4 | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEPACAM | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- HERC1 | c.9313G>A p.D3105N | Missense Mutation (SNP) | VAF 234/912 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- HOXD4 | c.366del p.S123Pfs*15 | Frame Shift Del (DEL) | VAF 182/747 reads (24%) | called by mutect2, pindel, varscan2
- HSP90AA1 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 188/691 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTR1A | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- IARS2 | c.1677A>T p.Q559H | Missense Mutation (SNP) | VAF 87/279 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ICE1 | c.5475G>T p.L1825F | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.295); called by muse, mutect2
- IGKV2D-24 | c.50-1G>T p.X17_splice | Splice Site (SNP) | VAF 20/88 reads (23%) | called by muse, varscan2
- IGKV3-11 | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 84/349 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- IGKV3-11 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 85/352 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- IGSF22 | c.46A>T p.M16L | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL13RA2 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2
- IMPG1 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 108/333 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- INHBE | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 84/378 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- INTS2 | c.376C>A p.L126M | Missense Mutation (SNP) | VAF 116/709 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IPPK | c.559T>C p.S187P | Missense Mutation (SNP) | VAF 76/244 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRX1 | c.433T>A p.W145R | Missense Mutation (SNP) | VAF 77/354 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IRX4 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 146/695 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITIH2 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 80/296 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- KANSL3 | c.561G>A p.W187* | Nonsense Mutation (SNP) | VAF 51/232 reads (22%) | called by muse, mutect2, varscan2
- KCNJ16 | c.515T>C p.M172T | Missense Mutation (SNP) | VAF 91/428 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KHDC1 | c.515G>T p.G172V (on ENST00000370384 / NM_001251874.2; = p.G99V on NM_030568.5) | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA2012 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 34/132 reads (26%) | called by muse, varscan2
- KIF4B | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 178/559 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- KIFAP3 | c.1944A>T p.E648D | Missense Mutation (SNP) | VAF 88/327 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIR2DL1 | c.901A>T p.T301S | Missense Mutation (SNP) | VAF 141/521 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- KL | c.1607C>G p.T536S | Missense Mutation (SNP) | VAF 96/445 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- KLF15 | c.218A>T p.Q73L | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- KLHL14 | c.1070-1G>T p.X357_splice | Splice Site (SNP) | VAF 80/221 reads (36%) | called by muse, mutect2, varscan2
- KLHL4 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP10-7 | c.361A>G p.K121E | Missense Mutation (SNP) | VAF 84/329 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAMC3 | c.616G>C p.A206P | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- LATS2 | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.515); called by muse, mutect2
- LCE1F | c.104del p.P35Lfs*43 | Frame Shift Del (DEL) | VAF 89/324 reads (27%) | called by mutect2, pindel, varscan2
- LDHD | c.778del p.L260Cfs*37 | Frame Shift Del (DEL) | VAF 37/131 reads (28%) | called by mutect2, pindel, varscan2
- LRRC40 | c.1687A>T p.N563Y | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MACC1 | c.268A>T p.R90* | Nonsense Mutation (SNP) | VAF 39/136 reads (29%) | called by muse, mutect2, varscan2
- MACF1 | c.9241A>C p.N3081H | Missense Mutation (SNP) | VAF 105/377 reads (28%) | called by muse, mutect2, varscan2
- MAGEA12 | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAML1 | c.2272G>T p.G758C | Missense Mutation (SNP) | VAF 86/386 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, varscan2
- MAP2K3 | c.535C>A p.H179N (on ENST00000342679 / NM_145109.3; = p.H150N on NM_002756.4) | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- MAPKBP1 | c.3236G>C p.G1079A (on ENST00000456763 / NM_001128608.2; = p.G1073A on NM_014994.3) | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- MB21D2 | c.574A>T p.I192F | Missense Mutation (SNP) | VAF 182/480 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- MCF2L | c.3254T>C p.V1085A (on ENST00000375608; = p.V1053A on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- MED25 | c.320dup p.G108Wfs*2 | Frame Shift Ins (INS) | VAF 46/193 reads (24%) | called by mutect2, pindel, varscan2
- MEIS2 | c.124G>T p.G42W (on ENST00000561208 / NM_170675.5; = p.G29W on NM_002399.3) | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MIOS | c.1525G>T p.G509W | Missense Mutation (SNP) | VAF 94/364 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- MOB2 | c.334A>G p.M112V | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MORC1 | c.1019A>C p.K340T | Missense Mutation (SNP) | VAF 74/353 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MOSMO | c.450T>G p.I150M | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL39 | c.482A>C p.E161A | Missense Mutation (SNP) | VAF 122/448 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- MT1G | c.131A>C p.K44T (on ENST00000379811 / NM_001301267.2; = p.K43T on NM_005950.3) | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- MUC16 | c.11790G>T p.E3930D | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MYH4 | c.4380del p.W1460* | Frame Shift Del (DEL) | VAF 27/74 reads (36%) | called by mutect2, pindel, varscan2
- MYH6 | c.4109T>G p.V1370G | Missense Mutation (SNP) | VAF 97/298 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO16 | c.1454T>C p.F485S | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- NACAD | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- NAV3 | c.4972C>A p.P1658T | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NCAM2 | c.1574T>A p.V525E | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- NCAM2 | c.2280C>A p.Y760* | Nonsense Mutation (SNP) | VAF 49/135 reads (36%) | called by muse, mutect2, varscan2
- NCOA6 | c.5371A>G p.T1791A | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCOR2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- NCR1 | c.356-2A>G p.X119_splice | Splice Site (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- NEBL | c.900C>G p.S300R | Missense Mutation (SNP) | VAF 195/669 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- NLRP8 | c.94T>A p.Y32N | Missense Mutation (SNP) | VAF 100/354 reads (28%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NME9 | c.667T>A p.C223S (on ENST00000333911 / NM_001349024.2; = p.C162S on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NOL4L | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- NPAS3 | c.1123G>T p.V375L (on ENST00000356141 / NM_001164749.2; = p.V343L on NM_022123.3) | Missense Mutation (SNP) | VAF 94/385 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- NPC1 | c.3577del p.H1193Tfs*49 | Frame Shift Del (DEL) | VAF 106/422 reads (25%) | called by mutect2, pindel, varscan2
- NR5A1 | c.174C>A p.D58E | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- NRXN3 | c.805C>T p.Q269* (on ENST00000557594 / NM_001272020.2; = p.Q901* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 83/361 reads (23%) | called by muse, mutect2, varscan2
- NSUN2 | c.1439del p.G480Vfs*5 | Frame Shift Del (DEL) | VAF 79/402 reads (20%) | called by mutect2, pindel, varscan2
- OPCML | c.204G>T p.W68C | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10A6 | c.130A>T p.I44F | Missense Mutation (SNP) | VAF 77/277 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- OR10R2 | c.667G>T p.G223* | Nonsense Mutation (SNP) | VAF 75/190 reads (39%) | called by muse, mutect2, varscan2
- OR2AK2 | c.775T>C p.Y259H | Missense Mutation (SNP) | VAF 78/285 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2M2 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- OR2M4 | c.308T>A p.F103Y | Missense Mutation (SNP) | VAF 94/392 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- OR2T10 | c.302T>A p.M101K | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- OR51F1 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5T1 | c.819A>T p.R273S | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PAPPA2 | c.2565G>T p.Q855H | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PCDHB6 | c.243T>A p.H81Q | Missense Mutation (SNP) | VAF 91/335 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCSK5 | c.2129G>C p.G710A | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCSK5 | c.3141G>T p.L1047F | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.086); called by muse, varscan2
- PDE7B | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 130/447 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- PGD | c.620A>G p.D207G | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.413); called by muse, varscan2
- PILRB | c.644G>C p.R215T | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, varscan2
- PITPNA | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 49/340 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1 | c.4209dup p.G1404Wfs*12 | Frame Shift Ins (INS) | VAF 247/661 reads (37%) | called by mutect2, pindel, varscan2
- PLK1 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- POLR3D | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 78/289 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POPDC3 | c.168G>T p.L56F | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POTEG | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); called by mutect2, varscan2
- PPP1R37 | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 41/137 reads (30%) | called by muse, mutect2, varscan2
- PPP1R3A | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 128/479 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PRDX6 | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 76/282 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- PTGR1 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RAB30 | c.221T>C p.I74T | Missense Mutation (SNP) | VAF 84/297 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- RALYL | c.24del p.S8Rfs*21 | Frame Shift Del (DEL) | VAF 54/221 reads (24%) | called by mutect2, pindel, varscan2
- RORA | c.1239G>A p.M413I (on ENST00000335670 / NM_134261.3; = p.M438I on NM_002943.3) | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RSPH6A | c.943G>T p.G315C | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RSPO3 | c.238T>C p.C80R | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RSPO3 | c.292T>A p.C98S | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RUNX1T1 | c.302C>A p.P101H (on ENST00000265814 / NM_001198628.1; = p.P74H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAMD9L | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 82/394 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SAMHD1 | c.1642-4A>T | Splice Region (SNP) | VAF 102/372 reads (27%) | called by muse, mutect2, varscan2
- SBSN | c.1648C>G p.Q550E (on ENST00000452271 / NM_001166034.2; = p.Q207E on NM_198538.4) | Missense Mutation (SNP) | VAF 90/314 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SCN10A | c.3659G>A p.W1220* | Nonsense Mutation (SNP) | VAF 57/170 reads (34%) | called by muse, mutect2, varscan2
- SCN3A | c.2535G>T p.E845D | Missense Mutation (SNP) | VAF 82/359 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SEC14L1 | c.559_560insTT p.T187Ifs*32 | Frame Shift Ins (INS) | VAF 127/595 reads (21%) | called by muse*, mutect2, varscan2*
- SEC14L1 | c.561_562del p.T188Lfs*32 | Frame Shift Del (DEL) | VAF 122/604 reads (20%) | called by muse*, mutect2, varscan2*
- SEC24A | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERINC2 | c.1140G>T p.E380D (on ENST00000373709 / NM_178865.5; = p.E384D on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/397 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- SGIP1 | c.801A>T p.L267F | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2
- SHANK1 | c.3904G>T p.E1302* | Nonsense Mutation (SNP) | VAF 48/136 reads (35%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.4466A>T p.Q1489L | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SLC10A2 | c.789del p.M264Cfs*42 | Frame Shift Del (DEL) | VAF 123/519 reads (24%) | called by mutect2, pindel, varscan2
- SLC24A4 | c.1414G>T p.V472L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SLC35A5 | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 110/505 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SLC39A1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC4A1 | c.752C>A p.A251E | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- SLC9A4 | c.884C>G p.T295S | Missense Mutation (SNP) | VAF 99/479 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SLCO1B1 | c.272T>A p.L91Q | Missense Mutation (SNP) | VAF 134/418 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLCO4C1 | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 78/306 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SOHLH1 | c.193C>G p.R65G | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SORCS1 | c.3385C>T p.P1129S | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPEF2 | c.2236A>T p.R746* | Nonsense Mutation (SNP) | VAF 116/540 reads (21%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.701C>A p.P234Q | Missense Mutation (SNP) | VAF 87/146 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SUPT20HL2 | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 86/145 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- TCEANC2 | c.176T>G p.L59R | Missense Mutation (SNP) | VAF 75/324 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- TEX51 | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- THOC6 | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 66/364 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THSD7B | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TLE2 | c.404del p.P135Lfs*157 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | called by pindel, varscan2
- TLR9 | c.1885G>T p.G629C | Missense Mutation (SNP) | VAF 95/377 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- TMEM45A | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 114/461 reads (25%) | called by muse, mutect2, varscan2
- TRIM36 | c.611A>T p.N204I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2
- TRIM58 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | called by muse, varscan2
- TTLL2 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.45847T>C p.Y15283H (on ENST00000591111; = p.Y7859H on NM_003319.4) | Missense Mutation (SNP) | VAF 190/647 reads (29%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.14191G>T p.D4731Y (on ENST00000591111; = p.D3804Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/174 reads (27%) | PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TTN | c.2344C>A p.Q782K (on ENST00000591111; = p.Q736K on NM_003319.4) | Missense Mutation (SNP) | VAF 80/269 reads (30%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UAP1 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 95/343 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP14 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.058); called by muse, varscan2
- USP21 | c.1076G>T p.W359L | Missense Mutation (SNP) | VAF 79/342 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- USP21 | c.1077G>T p.W359C | Missense Mutation (SNP) | VAF 79/343 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP33 | c.1101G>T p.K367N | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- USP33 | c.810G>A p.Q270= | Splice Region (SNP) | VAF 118/376 reads (31%) | called by muse, mutect2, varscan2
- USP35 | c.221A>T p.D74V | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VPS13B | c.1931C>G p.T644S | Missense Mutation (SNP) | VAF 129/413 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- VWA8 | c.1924C>G p.L642V | Missense Mutation (SNP) | VAF 115/407 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR87 | c.3749T>A p.M1250K | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ZNF385B | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF454 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF518A | c.2006C>G p.S669C | Missense Mutation (SNP) | VAF 83/237 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ZNF541 | c.1591C>A p.P531T | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.439); called by muse, varscan2
- ZNF717 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF729 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGB | c.315T>C p.D105= | Silent (SNP) | VAF 80/321 reads (25%) | called by muse, mutect2, varscan2
- ADGRB3 | c.3451C>A p.R1151= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV53233029, COSV53255498; called by muse, mutect2, varscan2
- ALPK3 | c.3390A>G p.A1130= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- ANK2 | c.1299A>G p.T433= | Silent (SNP) | VAF 179/470 reads (38%) | called by muse, varscan2
- ANKRD10 | c.30A>C p.V10= | Silent (SNP) | VAF 43/153 reads (28%) | called by muse, mutect2, varscan2
- ANKRD30A | c.423G>T p.T141= (on ENST00000611781; = p.T85= on NM_052997.2) | Silent (SNP) | VAF 111/403 reads (28%) | catalogued as rs751317438, COSV64606812; called by muse, mutect2, varscan2
- ARID2 | c.3084A>T p.V1028= | Silent (SNP) | VAF 94/301 reads (31%) | called by muse, mutect2, varscan2
- ARPP21 | c.579G>A p.S193= | Silent (SNP) | VAF 32/270 reads (12%) | catalogued as rs150267871; called by muse, mutect2, varscan2
- ASZ1 | c.94C>A p.R32= | Silent (SNP) | VAF 81/274 reads (30%) | catalogued as COSV52916699; called by muse, mutect2, varscan2
- C1orf194 | c.330C>T p.F110= (on ENST00000369948 / NM_001245025.3; = p.F98= on NM_001122961.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as rs774065695; called by muse, mutect2, varscan2
- CARD11 | c.3414G>A p.K1138= | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as COSV67796755; called by muse, mutect2, varscan2
- CDH5 | c.838C>T p.L280= | Silent (SNP) | VAF 50/172 reads (29%) | called by muse, mutect2, varscan2
- CP | c.1098C>A p.I366= | Silent (SNP) | VAF 83/454 reads (18%) | catalogued as COSV52831773; called by muse, mutect2, varscan2
- DNAH1 | c.7056C>T p.T2352= | Silent (SNP) | VAF 90/300 reads (30%) | catalogued as rs756999690; called by muse, mutect2, varscan2
- DNAJC10 | c.933T>C p.T311= | Silent (SNP) | VAF 83/321 reads (26%) | called by muse, mutect2, varscan2
- DSCAM | c.5253C>A p.T1751= | Silent (SNP) | VAF 36/200 reads (18%) | called by muse, mutect2, varscan2
- DZIP3 | c.3558G>C p.T1186= | Silent (SNP) | VAF 77/347 reads (22%) | catalogued as COSV64314056; called by muse, varscan2
- EGFLAM | c.2514G>T p.P838= (on ENST00000354891 / NM_001205301.2; = p.P830= on NM_152403.4) | Silent (SNP) | VAF 197/558 reads (35%) | catalogued as COSV59315694; called by muse, mutect2, varscan2
- EIF3I | c.726C>T p.D242= | Silent (SNP) | VAF 52/176 reads (30%) | called by muse, mutect2, varscan2
- EPB41L3 | c.2415G>C p.A805= | Silent (SNP) | VAF 85/480 reads (18%) | catalogued as COSV100550817, COSV59444169; called by muse, mutect2, varscan2
- EPHA7 | c.2907A>C p.T969= | Silent (SNP) | VAF 60/245 reads (24%) | called by muse, mutect2, varscan2
- FAM110B | c.171C>T p.D57= | Silent (SNP) | VAF 40/150 reads (27%) | catalogued as COSV100826286; called by muse, mutect2, varscan2
- FLG2 | c.7110C>T p.S2370= | Silent (SNP) | VAF 72/218 reads (33%) | called by muse, mutect2, varscan2
- FLNA | c.7800C>T p.P2600= (on ENST00000369850 / NM_001110556.2; = p.P2592= on NM_001456.3) | Silent (SNP) | VAF 73/135 reads (54%) | called by muse, mutect2, varscan2
- FNIP2 | c.909A>T p.P303= | Silent (SNP) | VAF 84/217 reads (39%) | called by muse, mutect2, varscan2
- FRMPD4 | c.996G>A p.R332= | Silent (SNP) | VAF 114/198 reads (58%) | called by muse, mutect2, varscan2
- FRY | c.2409A>T p.A803= | Silent (SNP) | VAF 118/470 reads (25%) | called by muse, mutect2, varscan2
- GGTLC1 | c.234T>C p.D78= | Silent (SNP) | VAF 34/112 reads (30%) | called by muse, mutect2, varscan2
- GOT1L1 | c.672G>A p.L224= | Silent (SNP) | VAF 31/113 reads (27%) | called by muse, mutect2, varscan2
- GPRIN3 | c.339G>T p.P113= | Silent (SNP) | VAF 48/93 reads (52%) | called by muse, mutect2, varscan2
- GRB14 | c.1176C>T p.P392= | Silent (SNP) | VAF 68/234 reads (29%) | called by muse, mutect2, varscan2
- H3-4 | c.396C>A p.R132= | Silent (SNP) | VAF 91/291 reads (31%) | called by muse, mutect2, varscan2
- HTR1A | c.825G>T p.L275= | Silent (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- HTR1E | c.417C>T p.A139= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs146428063, COSV100541098; called by muse, mutect2, varscan2
- IGKV1D-17 | c.27C>A p.L9= | Silent (SNP) | VAF 39/143 reads (27%) | called by muse, mutect2, varscan2
- INTS5 | c.258G>C p.R86= | Silent (SNP) | VAF 55/197 reads (28%) | catalogued as COSV57950612; called by muse, mutect2, varscan2
- ITGBL1 | c.969C>T p.S323= | Silent (SNP) | VAF 101/336 reads (30%) | called by muse, mutect2, varscan2
- KIAA0895 | c.114G>A p.E38= | Silent (SNP) | VAF 59/262 reads (23%) | catalogued as COSV99766602; called by muse, mutect2, varscan2
- KIAA1755 | c.453G>A p.E151= | Silent (SNP) | VAF 70/285 reads (25%) | catalogued as COSV99072171; called by muse, mutect2, varscan2
- LRP2 | c.1602G>T p.G534= | Silent (SNP) | VAF 139/452 reads (31%) | called by muse, mutect2, varscan2
- MAP3K11 | c.660G>T p.V220= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- MED13L | c.6632A>G p.*2211= | Silent (SNP) | VAF 124/484 reads (26%) | called by muse, mutect2, varscan2
- MEGF11 | c.2367C>T p.G789= | Silent (SNP) | VAF 60/196 reads (31%) | catalogued as rs1472589932; called by muse, mutect2, varscan2
- MROH2A | c.3486C>T p.L1162= | Silent (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- MROH9 | c.567A>G p.Q189= | Silent (SNP) | VAF 66/270 reads (24%) | called by muse, mutect2, varscan2
- MUC5B | c.11748C>T p.P3916= | Silent (SNP) | VAF 51/332 reads (15%) | called by muse, mutect2, varscan2
- MYO15B | c.3825G>C p.L1275= | Silent (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- NADK | c.1002C>A p.S334= | Silent (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
- NDFIP1 | c.219G>C p.L73= | Silent (SNP) | VAF 83/373 reads (22%) | called by muse, mutect2, varscan2
- NDN | c.813C>T p.T271= | Silent (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- NHSL2 | c.390G>A p.E130= (on ENST00000510661; = p.E496= on NM_001013627.2) | Silent (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2, varscan2
- NIPBL | c.1077A>G p.T359= | Silent (SNP) | VAF 133/483 reads (28%) | catalogued as rs767162047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OAS2 | c.378G>C p.G126= | Silent (SNP) | VAF 62/282 reads (22%) | catalogued as rs749120339; called by muse, mutect2, varscan2
- OR10G7 | c.240G>T p.L80= | Silent (SNP) | VAF 43/237 reads (18%) | catalogued as COSV100390027; called by muse, mutect2, varscan2
- OR4K2 | c.231C>A p.A77= | Silent (SNP) | VAF 48/305 reads (16%) | called by mutect2, varscan2
- OR51V1 | c.174G>T p.L58= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV58314816; called by muse, mutect2, varscan2
- OR6K2 | c.21C>T p.T7= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs1461733291, COSV62743291; called by muse, mutect2
- OR8J3 | c.516T>C p.N172= | Silent (SNP) | VAF 39/149 reads (26%) | called by muse, mutect2, varscan2
- PABPN1L | c.153A>G p.K51= | Silent (SNP) | VAF 75/328 reads (23%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1830C>T p.A610= | Silent (SNP) | VAF 60/473 reads (13%) | called by mutect2, varscan2
- PDGFB | c.48T>C p.R16= | Silent (SNP) | VAF 33/207 reads (16%) | called by muse, mutect2, varscan2
- PIWIL1 | c.1504C>A p.R502= | Silent (SNP) | VAF 69/331 reads (21%) | catalogued as COSV99806920; called by muse, mutect2, varscan2
- PLCH1 | c.1059A>T p.G353= (on ENST00000340059 / NM_001130960.2; = p.G365= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/306 reads (20%) | called by muse, mutect2, varscan2
- PLCH2 | c.168G>A p.V56= | Silent (SNP) | VAF 69/236 reads (29%) | called by muse, mutect2, varscan2
- PSG2 | c.219G>A p.R73= | Silent (SNP) | VAF 124/560 reads (22%) | called by muse, varscan2
- PSPC1 | c.1434T>A p.P478= | Silent (SNP) | VAF 47/418 reads (11%) | called by muse, varscan2
- PTPRC | c.543T>A p.P181= | Silent (SNP) | VAF 296/1078 reads (27%) | called by muse, mutect2, varscan2
- QRICH1 | c.450C>T p.S150= | Silent (SNP) | VAF 86/266 reads (32%) | called by muse, mutect2, varscan2
- RAC2 | c.159G>T p.L53= | Silent (SNP) | VAF 97/436 reads (22%) | called by muse, mutect2, varscan2
- RANBP10 | c.1773C>T p.A591= | Silent (SNP) | VAF 42/154 reads (27%) | catalogued as rs1250772967; called by muse, mutect2, varscan2
- RTL1 | c.1791G>A p.Q597= | Silent (SNP) | VAF 70/316 reads (22%) | catalogued as COSV66016362; called by muse, mutect2, varscan2
- RTN1 | c.1818G>T p.G606= | Silent (SNP) | VAF 95/373 reads (25%) | called by muse, mutect2, varscan2
- RXFP3 | c.1251C>A p.P417= | Silent (SNP) | VAF 68/221 reads (31%) | called by muse, mutect2, varscan2
- SAMD7 | c.1143T>C p.I381= | Silent (SNP) | VAF 135/617 reads (22%) | called by muse, mutect2, varscan2
- SGIP1 | c.799T>C p.L267= | Silent (SNP) | VAF 33/136 reads (24%) | catalogued as COSV52762792; called by muse, mutect2
- SIGLEC1 | c.741C>T p.P247= | Silent (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- SIGLEC5 | c.900G>A p.E300= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as COSV55783570; called by muse, mutect2, varscan2
- SLC44A5 | c.1032C>A p.I344= | Silent (SNP) | VAF 123/482 reads (26%) | catalogued as rs747545774; called by muse, mutect2, varscan2
- SLITRK4 | c.1617G>A p.L539= | Silent (SNP) | VAF 70/113 reads (62%) | called by muse, mutect2, varscan2
- SOGA3 | c.432G>A p.E144= | Silent (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- SORCS1 | c.1347C>A p.T449= | Silent (SNP) | VAF 60/264 reads (23%) | called by muse, mutect2, varscan2
- SPR | c.174G>T p.R58= | Silent (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- SYNE1 | c.15219G>A p.Q5073= (on ENST00000367255 / NM_182961.4; = p.Q5002= on NM_033071.3) | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as rs1563086001; called by muse, mutect2, varscan2
- TANGO6 | c.1656A>G p.K552= | Silent (SNP) | VAF 34/93 reads (37%) | called by muse, mutect2, varscan2
- TENM2 | c.246C>A p.A82= | Silent (SNP) | VAF 68/329 reads (21%) | called by muse, mutect2, varscan2
- TLE2 | c.414C>G p.L138= | Silent (SNP) | VAF 38/82 reads (46%) | called by muse, varscan2
- TMPRSS11A | c.510G>A p.G170= | Silent (SNP) | VAF 84/264 reads (32%) | called by muse, mutect2, varscan2
- TNXB | c.7143G>T p.G2381= (on ENST00000647633; = p.G2134= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 208/431 reads (48%) | called by muse, mutect2, varscan2
- TSPEAR | c.849C>A p.A283= | Silent (SNP) | VAF 71/241 reads (29%) | called by muse, mutect2, varscan2
- USPL1 | c.933T>C p.V311= | Silent (SNP) | VAF 62/288 reads (22%) | called by muse, mutect2, varscan2
- WDR87 | c.2205T>C p.D735= | Silent (SNP) | VAF 53/209 reads (25%) | catalogued as rs1175374517; called by muse, mutect2, varscan2
- XPOT | c.2271A>G p.V757= | Silent (SNP) | VAF 21/69 reads (30%) | called by muse, varscan2
- ZBBX | c.1023G>T p.T341= | Silent (SNP) | VAF 48/403 reads (12%) | catalogued as COSV56791098; called by muse, mutect2, varscan2
- ZNF236 | c.2413C>T p.L805= | Silent (SNP) | VAF 81/268 reads (30%) | called by muse, mutect2, varscan2
- ZNF671 | c.198T>C p.L66= | Silent (SNP) | VAF 43/178 reads (24%) | called by muse, mutect2, varscan2
- ZNF865 | c.2262G>A p.A754= | Silent (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- ABCA6 | c.2740+26C>G | Intron (SNP) | VAF 49/277 reads (18%) | called by muse, mutect2, varscan2
- AC007557.3 | n.2679A>G | RNA (SNP) | VAF 86/327 reads (26%) | called by muse, mutect2, varscan2
- AC099552.1 | n.260C>A | RNA (SNP) | VAF 113/541 reads (21%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1111A>T | RNA (SNP) | VAF 60/292 reads (21%) | called by muse, varscan2
- ADAT1 | c.238+613A>C | Intron (SNP) | VAF 34/484 reads (7%) | catalogued as rs1187792420; called by muse, mutect2
- AFDN | c.4812+2293C>G | Intron (SNP) | VAF 30/379 reads (8%) | catalogued as rs1262530153; called by muse, mutect2
- AGTPBP1 | c.-165C>G | 5'UTR (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821868 T>A | 5'Flank (SNP) | VAF 86/165 reads (52%) | called by muse, mutect2, varscan2
- ANKRD30B | c.2313+156C>T | Intron (SNP) | VAF 47/225 reads (21%) | catalogued as rs765065736, COSV62824004; called by muse, mutect2, varscan2
- BCAR1 | chr16:75266727 del G | 5'Flank (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- CEP41 | c.*2006G>A | 3'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- CFAP46 | c.3219+95C>G | Intron (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*33G>A | 3'UTR (SNP) | VAF 165/644 reads (26%) | catalogued as rs1198865884; called by muse, mutect2, varscan2
- CIDEA | c.38+26G>C | Intron (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2
- CTDP1 | chr18:79679592 T>A | 5'Flank (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- DNAH14 | c.1032+6533A>G | Intron (SNP) | VAF 68/215 reads (32%) | called by muse, mutect2, varscan2
- EFHB | c.1725+44G>C | Intron (SNP) | VAF 49/492 reads (10%) | called by muse, mutect2, varscan2
- EGR2 | c.-14T>A | 5'UTR (SNP) | VAF 156/547 reads (29%) | called by muse, mutect2, varscan2
- ESPNP | n.1483G>C | RNA (SNP) | VAF 68/550 reads (12%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445932 C>G | 3'Flank (SNP) | VAF 60/214 reads (28%) | called by muse, mutect2, varscan2
- FEZ1 | chr11:125496684 G>T | 5'Flank (SNP) | VAF 108/392 reads (28%) | called by muse, mutect2, varscan2
- FXN | chr9:69035749 T>C | 5'Flank (SNP) | VAF 29/141 reads (21%) | called by muse, mutect2, varscan2
- HEXB | c.-28A>T | 5'UTR (SNP) | VAF 13/64 reads (20%) | catalogued as rs1342723195; called by muse, mutect2, varscan2
- HOXD13 | c.*4G>A | 3'UTR (SNP) | VAF 71/259 reads (27%) | called by muse, mutect2, varscan2
- HPS5 | c.1510+38C>A | Intron (SNP) | VAF 93/431 reads (22%) | called by muse, mutect2, varscan2
- KCNA1 | c.-17C>A | 5'UTR (SNP) | VAF 58/180 reads (32%) | catalogued as rs746212583, COSV66836806; called by muse, mutect2, varscan2
- KIAA0895 | c.868-1042G>T | Intron (SNP) | VAF 46/266 reads (17%) | called by muse, mutect2, varscan2
- KLHL21 | c.1500+96G>A | Intron (SNP) | VAF 38/130 reads (29%) | called by muse, mutect2, varscan2
- KRTAP2-2 | c.*124T>C | 3'UTR (SNP) | VAF 25/101 reads (25%) | catalogued as rs1359278622; called by muse, varscan2
- L3MBTL3 | c.215-94G>A | Intron (SNP) | VAF 33/118 reads (28%) | called by muse, varscan2
- LGALS8 | c.-104+103C>T | Intron (SNP) | VAF 102/347 reads (29%) | called by muse, mutect2, varscan2
- LILRB1 | c.1800+208C>A | Intron (SNP) | VAF 36/136 reads (26%) | called by muse, varscan2
- LILRB1 | c.1800+209C>A | Intron (SNP) | VAF 36/133 reads (27%) | called by muse, varscan2
- LINC02551 | n.1012A>T | RNA (SNP) | VAF 71/346 reads (21%) | called by muse, mutect2, varscan2
- LINC02876 | n.432A>T | RNA (SNP) | VAF 30/101 reads (30%) | called by muse, varscan2
- MIR296 | n.24del | RNA (DEL) | VAF 44/216 reads (20%) | catalogued as rs747039644; called by mutect2, pindel, varscan2
- MIR525 | n.38T>A | RNA (SNP) | VAF 86/320 reads (27%) | called by muse, mutect2, varscan2
- MIR526B | n.42G>C | RNA (SNP) | VAF 39/222 reads (18%) | called by muse, mutect2, varscan2
- MIR758 | n.88C>T | RNA (SNP) | VAF 62/253 reads (25%) | catalogued as rs571084935; called by muse, mutect2, varscan2
- MS4A6E | c.147+562C>A | Intron (SNP) | VAF 35/198 reads (18%) | catalogued as rs1565156138; called by muse, mutect2, varscan2
- MSRA | c.142+41380C>G | Intron (SNP) | VAF 35/182 reads (19%) | called by muse, mutect2, varscan2
- NXF5 | n.1536T>A | RNA (SNP) | VAF 89/145 reads (61%) | called by muse, mutect2, varscan2
- OBP2A | c.*47C>T | 3'UTR (SNP) | VAF 34/233 reads (15%) | called by muse, mutect2, varscan2
- OR5H15 | c.926-42A>G | Intron (SNP) | VAF 71/275 reads (26%) | called by muse, mutect2, varscan2
- PCCA | c.-8G>T | 5'UTR (SNP) | VAF 30/124 reads (24%) | called by muse, mutect2, varscan2
- PDE6B | c.927+11G>C | Intron (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- POPDC2 | c.1010-861A>T | Intron (SNP) | VAF 68/528 reads (13%) | called by muse, varscan2
- PPP1R13L | c.-11C>T | 5'UTR (SNP) | VAF 43/248 reads (17%) | catalogued as COSV100714851; called by muse, mutect2, varscan2
- PRMT1 | chr19:49677221 del G | 5'Flank (DEL) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- PRPF40B | c.-51T>G | 5'UTR (SNP) | VAF 79/350 reads (23%) | called by muse, mutect2, varscan2
- PRSS1 | c.200+388T>C | Intron (SNP) | VAF 71/323 reads (22%) | called by muse, mutect2, varscan2
- RACK1 | c.109+338A>G | Intron (SNP) | VAF 57/213 reads (27%) | catalogued as rs780570953; called by muse, mutect2, varscan2
- RCC1 | c.-228-178del | Intron (DEL) | VAF 198/793 reads (25%) | called by mutect2, pindel, varscan2
- RN7SKP78 | chr10:6146423 G>T | 5'Flank (SNP) | VAF 71/294 reads (24%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1207G>C | RNA (SNP) | VAF 89/267 reads (33%) | called by muse, mutect2, varscan2
- RPS26P15 | n.51C>G | RNA (SNP) | VAF 84/351 reads (24%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.88+13261C>T | Intron (SNP) | VAF 16/47 reads (34%) | catalogued as rs999206743, COSV56148063; called by muse, mutect2, varscan2
- SGIP1 | c.1571-22G>T | Intron (SNP) | VAF 147/543 reads (27%) | catalogued as rs371954900; called by muse, mutect2, varscan2
- SLC45A2 | c.1368+52G>C | Intron (SNP) | VAF 70/266 reads (26%) | catalogued as rs1239533619; called by muse, mutect2, varscan2
- SLC45A2 | c.1368+51G>T | Intron (SNP) | VAF 71/272 reads (26%) | called by muse, mutect2, varscan2
- SNORD115-1 | n.63A>G | RNA (SNP) | VAF 72/405 reads (18%) | catalogued as rs747347812; called by muse, mutect2, varscan2
- SNORD115-33 | n.48T>G | RNA (SNP) | VAF 28/202 reads (14%) | catalogued as rs532109308; called by muse, mutect2, varscan2
- SNRNP200 | c.4004-24C>G | Intron (SNP) | VAF 41/202 reads (20%) | catalogued as rs1259850718; called by muse, mutect2, varscan2
- SNX19 | chr11:130861970 C>G | 3'Flank (SNP) | VAF 43/152 reads (28%) | called by muse, mutect2, varscan2
- SOX5 | c.-39G>A | 5'UTR (SNP) | VAF 118/442 reads (27%) | called by muse, varscan2
- SSC5D | c.2785+2974G>T | Intron (SNP) | VAF 53/210 reads (25%) | called by muse, mutect2, varscan2
- STAG3L4 | n.549C>T | RNA (SNP) | VAF 40/152 reads (26%) | catalogued as rs1315574304; called by muse, mutect2, varscan2
- TIRAP | c.-50C>T | 5'UTR (SNP) | VAF 75/174 reads (43%) | called by muse, mutect2, varscan2
- TPD52L1 | c.-21C>T | 5'UTR (SNP) | VAF 60/255 reads (24%) | called by muse, mutect2, varscan2
- TPRX2P | n.98G>C | RNA (SNP) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- UQCRC1 | c.*49C>A | 3'UTR (SNP) | VAF 28/90 reads (31%) | called by mutect2, varscan2
- ZNF606 | c.-150C>A | 5'UTR (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
